MMRF case MMRF_1318 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0b61653c-1e82-4624-8c33-df8661782b40

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 85 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 85.4 years (31,200 days); ISS stage: III; Days to last known disease status: 1,457 days (4.0 years); Days to last follow up: 1,457 days (4.0 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 29 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 204 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 29 days; Days to treatment end: 113 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 29 days; Days to treatment end: 85 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 85 days; Days to treatment end: 155 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 113 days; Days to treatment end: 368 days (1.0 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 162 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 211 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 379 days (1.0 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 1): M Protein 5.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 289 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.127 mg/dL; Immunoglobulin G 1 g/L; Immunoglobulin A 44.8 g/L; Immunoglobulin M 0.03 g/L; Beta 2 Microglobulin 12.6 µg/mL; Lactate Dehydrogenase 1.82 µkat/L; Hemoglobin 5.58 mmol/L; Leukocytes 8.7 ×10⁹/L; Absolute Neutrophil 6.35 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 1.98 mmol/L; Albumin 24 g/L; Total Protein 10.8 g/dL; Glucose 6.33 mmol/L; C-Reactive Protein 0.3 mg/dL.
- Day 85 (ECOG 1): M Protein 3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 88.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.801 mg/dL; Immunoglobulin G 1.23 g/L; Immunoglobulin A 33.8 g/L; Immunoglobulin M 0.05 g/L; Hemoglobin 6.08 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 257 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 1.98 mmol/L; Albumin 32 g/L; Total Protein 7.7 g/dL; Glucose 6.66 mmol/L.
- Day 183 (ECOG 1): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.83 mg/dL; Immunoglobulin G 2.47 g/L; Immunoglobulin A 2.55 g/L; Immunoglobulin M 0.06 g/L; Hemoglobin 8 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 3.49 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.18 mmol/L; Albumin 42 g/L; Total Protein 6.1 g/dL; Glucose 5.94 mmol/L.
- Day 260 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.667 mg/dL; Immunoglobulin G 3.05 g/L; Immunoglobulin A 1.28 g/L; Immunoglobulin M 0.08 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.42 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.05 mmol/L; Albumin 41 g/L; Total Protein 6 g/dL; Glucose 5.61 mmol/L.
- Day 358 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 3.81 g/L; Immunoglobulin A 0.82 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 3.71 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.1 mmol/L; Albumin 39 g/L; Total Protein 5.9 g/dL; Glucose 5.83 mmol/L.
- Day 435 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.907 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.16 mg/dL; Immunoglobulin G 3.6 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.14 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 7.1 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.13 mmol/L; Albumin 40 g/L; Total Protein 6 g/dL; Glucose 7.43 mmol/L.
- Day 547 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.12 mg/dL; Immunoglobulin G 4.99 g/L; Immunoglobulin A 0.83 g/L; Immunoglobulin M 0.14 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.36 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.2 mmol/L; Albumin 42 g/L; Total Protein 6.2 g/dL; Glucose 6.55 mmol/L.
- Day 631 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.14 mg/dL; Immunoglobulin G 5.15 g/L; Immunoglobulin A 0.92 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.64 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 6.1 g/dL; Glucose 5.56 mmol/L.
- Day 729 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.87 mg/dL; Immunoglobulin G 4.95 g/L; Immunoglobulin A 0.93 g/L; Immunoglobulin M 0.16 g/L; Hemoglobin 8.68 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 3.82 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.3 g/dL; Glucose 5.34 mmol/L.
- Day 813 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.08 mg/dL; Immunoglobulin G 4.59 g/L; Immunoglobulin A 1.19 g/L; Immunoglobulin M 0.18 g/L; Hemoglobin 8.62 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 1.92 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.1 g/dL; Glucose 6.33 mmol/L.
- Day 897 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.17 mg/dL; Immunoglobulin G 4.82 g/L; Immunoglobulin A 1.59 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 8.68 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.03 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 6.33 mmol/L.
- Day 981 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.45 mg/dL; Immunoglobulin G 5.12 g/L; Immunoglobulin A 2.81 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.25 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 5.89 mmol/L.
- Day 1,065 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 5.01 g/L; Immunoglobulin A 3.36 g/L; Immunoglobulin M 0.22 g/L; Hemoglobin 8.87 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.55 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.1 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 6.93 mmol/L.
- Day 1,177 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 5.16 g/L; Immunoglobulin M 0.17 g/L; Hemoglobin 8.99 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.38 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 6.05 mmol/L.
- Day 1,261 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.99 mg/dL; Immunoglobulin G 4.52 g/L; Immunoglobulin A 4.64 g/L; Immunoglobulin M 0.17 g/L; Hemoglobin 8.49 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 6 g/dL; Glucose 6.99 mmol/L.
- Day 1,373 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.24 mg/dL; Immunoglobulin G 5.75 g/L; Immunoglobulin A 5.3 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2.99 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 5.23 mmol/L.
- Day 1,457 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.63 mg/dL; Immunoglobulin G 4.71 g/L; Immunoglobulin A 2.81 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.31 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.15 mmol/L; Albumin 37 g/L; Total Protein 6.1 g/dL; Glucose 5.39 mmol/L.

Other clinical attributes
- Day -6: Weight: 60 kg; Height: 165 cm.

Biospecimens (2 samples)
- Sample MMRF_1318_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_1318_2_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
